TCGA case TCGA-WK-A8XO — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Brigham and Women's Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fbc32608-52ae-48ca-bb4a-ec29c1d82b8b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 363 days.

Diagnoses (3)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,201 days); Year of diagnosis: 2010; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Contiguous organ invaded: Colon; Sites of involvement: Colon, NOS; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 6.6.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 8.1.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Peritoneum, NOS. Age at diagnosis: 66.5 years (24,306 days); Days to diagnosis: 105 days; Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Tumor burden: 1.1.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Abdomen, NOS. Age at diagnosis: 66.5 years (24,306 days); Days to diagnosis: 105 days; Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Tumor burden: 1.5.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 3.
- Day 105 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 105 days.
- Day 105 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 105 days.
- Days to follow up: 363 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WK-A8XO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-WK-A8XO-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WK-A8XO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WK-A8XO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum; Submitted tumor site: Retroperitoneum/Upper abdominal - Small Intestines; Submitted tumor site: Retroperitoneum/Upper abdominal - Other (please specify.
- Primary pathology: Site of primary tumor other: Omentum; Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: Yes; Discontinuous lesions count: 3; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No; Contiguous organ invaded: Yes; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 5.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 363 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 363 days; disease-free interval: event (new tumor event after initially disease-free), 105 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 105 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WK-A8XO-01A-11D-A37B-01): tumor purity 0.58, ploidy 1.92, whole-genome doublings 0.
